Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4891, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4891-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA - CJ - 4891

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA (8.5 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE (70% CLEAR CELLS, 30% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 4, INVASIVE INTO RENAL VEIN, ADRENAL VEIN, RENAL SINUS ADIPOSE TISSUE AND PERINEPHRIC ADIPOSE TISSUE. (SEE COMMENT)

Adrenal gland, no tumor present.

Five lymph nodes, no tumor present.

(B) THROMBUS:

CONVENTIONAL RENAL CELL CARCINOMA, THROMBUS AND, BLOOD VESSEL WALL.

(C) PARA-AORTIC AND RETROAORTIC LYMPH NODES:

Five lymph nodes, no tumor present.

Ganglia, no tumor present.

COMMENT

The renal cell carcinoma in the left kidney shows extensive areas of necrosis. The tumor and the adjacent normal also show the presence of foreign material within some of the arterioles and necrosis, which is more marked in the normal kidney. The tumor protrudes beyond the renal vein margin and is present within the lumen of the renal vein at the margin. However, the wall of the renal vein at the margin is not involved by tumor.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A left radical nephrectomy specimen (17.0 x 11.0 x 7.5 cm), with a ureter (8.0 cm in length by 0.8 cm in diameter) and adrenal gland (6.0 x 2.0 x 1.0 cm). There is a tumor involving the upper pole of the kidney (8.5 x 6.2 x 4.5 cm). The tumor extends to involve the renal sinus and perirenal adipose tissue, and tumor thrombus is found within the renal vein and adrenal vein. The tumor protrudes beyond the renal vein margin. The tumor is 80% necrotic with a yellow and brown areas, and a focal calcified area.

The remaining renal parenchyma shows cortical necrosis. The adrenal gland is unremarkable. Five possible lymph nodes near the renal hilum (1.8 x 1.3 x 1.2 cm to 1.1 x 0.7 x 0.5 cm) are identified.

A portion of the tumor from both yellow and brown areas is submitted for electron microscopy.

INK CODE: Black - surface at the perirenal fat.

SECTION CODE: A1, ureteral margin; A2, renal vein margin; A3, renal artery margin; A4-A6, tumor with perinephric fat margin, perpendicular; A7, tumor and perinephric fat; A8-A9, tumor and renal sinus; A10, yellow area of tumor; A11-A12, brown area of tumor; A13, additional section of tumor with adjacent kidney; A14, adrenal vein with tumor; A15, renal vein with tumor; A16, adrenal gland, representative section; A17-A18, uninvolved renal parenchyma; A19-A20, largest possible single lymph node; A21, one possible lymph node, bisected; A22, three lymph nodes [REDACTED]

(B) THROMBUS - A lobulated, tan-white mass (12.0 x 6.3 x 4.4 cm) with variegated and partially hemorrhagic cut surface and attached fibrin and clotted blood. Within the container, there is also a segment of vessel (2.7 length, 2.3 cm diameter) filled with a thrombus. The vessel has one of the ends marked with surgical sutures.

SECTION CODE: B1, vascular resection margin marked by sutures; B2, vascular resection margin without suture; B3, representative section of vascular wall and thrombus; B4-B7, representative sections of the mass. [REDACTED]

(C) PARA-AORTIC LYMPH NODE - Three irregular fragments of fibroconnective and adipose tissue (5.3 x 2.3 x 1.0 cm in aggregate) that contain multiple unremarkable lymph nodes (ranging from 1.8 x 1.0 x 0.6 cm to 0.3 x 0.3 x 0.2 cm).

SECTION CODE: C1, one bisected lymph node; C2-C3, one serially sectioned possible lymph node; C4, one possible bisected lymph node; C5, four possible lymph nodes. [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123, T-C4400, M-00110

Source: NCI Genomic Data Commons file 1857a4fa-70e1-49c3-aed2-acf950ca7041 (TCGA-CJ-4891.C76D94F0-A660-4C98-9114-E119FF120CDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).